Somatic mutation profile of tumor specimen 0DPL7P from CCDI case PBCDMN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 2.9 years (1,049 days).
Specimen 0DPL7P: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c5fdaff3-e818-4572-87d9-b1d6b3dc7c89.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPL7H (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fe32018e-b192-4875-9899-553f03dac447

The open-access MAF lists 20 somatic variants for this specimen: 14 protein-altering or splice-affecting, 2 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Intron 2, Silent 2, 3'UTR 1, Nonsense Mutation 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATR | c.7376G>A p.R2459H | Missense Mutation (SNP) | VAF 76/596 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs754253403, COSV63387628; called by muse, mutect2, varscan2
- CLTCL1 | c.3734G>C p.R1245P | Missense Mutation (SNP) | VAF 64/429 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as rs782735553, COSV54230140; called by muse, mutect2, varscan2
- CNGA2 | c.1201G>T p.V401F | Missense Mutation (SNP) | VAF 26/634 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61703027; called by muse, mutect2
- COL7A1 | c.6190G>T p.G2064* | Nonsense Mutation (SNP) | VAF 173/507 reads (34%) | catalogued as CM980411, COSV60396432; called by muse, mutect2, varscan2
- FAM53B | c.775C>T p.R259C | Missense Mutation (SNP) | VAF 211/436 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs779220632, COSV55101144; called by muse, mutect2, varscan2
- SH3D19 | c.863C>T p.T288I | Missense Mutation (SNP) | VAF 114/770 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.717); catalogued as rs928933703; called by muse, mutect2, varscan2
- ZMYND10 | c.728G>A p.R243H | Missense Mutation (SNP) | VAF 36/502 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs201582591; called by muse, mutect2
- ALDH3A2 | c.26G>C p.R9P | Missense Mutation (SNP) | VAF 52/625 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- COL3A1 | c.1252C>A p.P418T | Missense Mutation (SNP) | VAF 158/540 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- FIBP | c.223A>G p.K75E | Missense Mutation (SNP) | VAF 12/361 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, mutect2
- NAALAD2 | c.202A>G p.T68A | Missense Mutation (SNP) | VAF 19/320 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.153); called by muse, mutect2
- PPM1E | c.1222C>T p.H408Y | Missense Mutation (SNP) | VAF 26/446 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.316); called by muse, mutect2
- RGS21 | c.376C>G p.R126G | Missense Mutation (SNP) | VAF 239/783 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- THAP10 | c.142A>C p.N48H | Missense Mutation (SNP) | VAF 14/212 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.892); called by muse, mutect2
- AKAP6 | c.4287C>T p.S1429= | Silent (SNP) | VAF 24/580 reads (4%) | called by muse, mutect2
- MYO7A | c.3282C>T p.G1094= | Silent (SNP) | VAF 89/317 reads (28%) | catalogued as rs1470394833, COSV68687581; called by muse, mutect2, varscan2
- ARL6IP5 | c.394+47G>A | Intron (SNP) | VAF 93/274 reads (34%) | called by muse, mutect2, varscan2
- COL4A3 | c.609+59A>T | Intron (SNP) | VAF 23/443 reads (5%) | called by muse, mutect2
- SMG7 | c.*1239C>T | 3'UTR (SNP) | VAF 30/944 reads (3%) | called by muse, mutect2
- TNRC18 | chr7:5428090 G>T | 5'Flank (SNP) | VAF 48/266 reads (18%) | called by muse, mutect2, varscan2
